OHSU case 4977 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/c8134666-9c89-4423-814c-a3bf1b6a712c

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Chronic myelomonocytic leukemia, NOS: ICD-O-3 morphology code: 9945/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Age at diagnosis: 84.0 years (30,681 days).

Biospecimens (1 sample)
- Sample 2415D: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
